Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4V5, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4V5-01A (Primary Tumor).

[page 1 of 3]
id & Neck
J And Neck

Billing type:
Additional Copy to:

Clinical Diagnosis & History:

Papillary carcinoma of right thyroid.

Specimens Submitted:

- 1: Delphain lymph node
- 2: Total thyroidectomy central compartment lymph node
- 3: Right para-esophageal lymph node

DIAGNOSIS:

1. Delphain lymph node; excision:
- Three out of four lymph nodes positive for metastatic papillary thyroid carcinoma (3/4).
- The largest lymph node measures 0.5 cm.
- The largest metastatic focus measures 0.3 cm.
- No extranodal extension seen.
- A separate fragment of thyroid with chronic lymphocytic thyroiditis.

2. Total thyroidectomy central compartment lymph node:

Part # 2

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Marked stromal reaction

Psammoma bodies

Extensive squamous metaplasia

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 4.1 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

ICD-0-3

carcinoma, papillary, thyroid, 8260/3

Site: thyroid, NOS C73.9

ju
10/27/12

[page 2 of 3]
Not Identified

Extrathyroid Extension:

Invades: perithyroidal tissue

Surgical Margins:

Tumor is present focally at the inked posterior margin

Tumor Multicentricity:

Not Identified

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Identified

One parathyroid gland seen

Lymph Nodes:

Tumor is present in eight lymph nodes (8/8). The largest positive lymph node measures 0.9 cm and the largest metastatic focus measures 0.7 cm.

Comment: Extensive psammoma bodies are noted in the non-neoplastic thyroid.

3. Right para-esophageal lymph node; excision:

- Four out of five lymph nodes positive for metastatic carcinoma (4/5).
- Largest lymph node measures 1.1 cm and is almost entirely involved by metastatic carcinoma.
- No extranodal extension seen.
- Benign parathyroid gland.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "Delphian lymph node", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

2. The specimen is received fresh, labeled "total thyroidectomy central compartment lymph node dissection", and consists of a thyroid weighing 39g. The right lobe measures 5 cm x 4 cm x 2.0 cm, the left lobe measures 5 cm x 2.5 cm x 1.0 cm and the isthmus measures 1.0 cm x 0.8 cm x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals one nodule. The nodule is located in the right lobe and measures 4.1 cm x 3.2 cm x 1.0 cm and it is in contact with the capsule, displays firm cut surfaces, and is not encapsulated. Sections through the remaining tissue reveal no other lesions. The remaining thyroid parenchyma is red brown and beefy. Various lymph nodes are identified measuring from 0.3 cm to 0.5 cm. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RN - right nodule, entirely submitted

RL - right lobe

[page 3 of 3]
LL - left lobe
IS - Isthmus
LN- lymph nodes

3. The specimen is received fresh, labeled "right paraesophageal lymph nodes", and consists of multiple pink tan firm lymph nodes ranging from 0.6 to 1.1 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:
BLN - bisected lymph nodes
LN - lymph nodes

Summary of Sections:

Part 1: Delphain lymph node

Block	Sect. Site	PCs
2	LN	2

Part 2: Total thyroidectomy central compartment lymph node

Block	Sect. Site	PCs
2	IST	2
3	LL	3
3	LN	3
1	RL	1
8	RN	8

Part 3: Right para-esophageal lymph node

Block	Sect. Site	PCs
3	BLN	3
1	LN	1

10/27/12

Source: NCI Genomic Data Commons file 4aa25c8f-2dae-4271-9f99-6781a85570d1 (TCGA-DJ-A4V5.E4745F67-4727-4DF5-826A-3CEA904ED623.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).